TCGA case TCGA-WK-A8XQ — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Brigham and Women's Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/788dbebb-3d1b-4f6d-8a40-869157d25025

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Dead; Days to death: 146 days.

Diagnoses (3)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 57.2 years (20,891 days); Year of diagnosis: 2009; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Sites of involvement: Omentum; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 36.5.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 19.8; Tumor length measurement: 14.1; Tumor width measurement: 27.8.
   Pathology details: Measurement type: Radiologic; Tumor burden: 27.8.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 50; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 36.5.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Pelvis, NOS. Age at diagnosis: 57.3 years (20,918 days); Days to diagnosis: 27 days; Prior treatment: Yes.
3. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Abdomen, NOS. Age at diagnosis: 57.3 years (20,918 days); Days to diagnosis: 27 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 27 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 27 days.
- Day 27 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Abdomen, NOS; Days to recurrence: 27 days.
- Days to follow up: 146 days; Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WK-A8XQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-WK-A8XQ-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WK-A8XQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WK-A8XQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Intraabdominal; Submitted tumor site: Retroperitoneum/Upper abdominal - Other (please specify.
- Primary pathology: Site of primary tumor other: Mesentery; Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: No; Contiguous organ resection: Omentum; Contiguous organ invaded: Yes; Well diff liposarc prior diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 146 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 146 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 27 days.
